Gene-level copy-number profile of tumor specimen TCGA-44-6777-01A from TCGA case TCGA-44-6777, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 85.5 years (31,234 days).
Specimen TCGA-44-6777-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.5c61de6e-6a7e-447a-9d19-b5e3927faec7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-6777-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/69769300-711d-46f7-ad03-0253c44d15ed

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 793; copy number 2: 15,907; copy number 3: 23,568; copy number 4: 14,428; copy number 5: 4,331; copy number 11: 114; copy number 13: 193; copy number 15: 83; copy number 16: 122; copy number 17: 220; copy number 19: 41; copy number 30: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-6777-01A-11D-1854-01): tumor purity 0.34, ploidy 1.82, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 793 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–55,425,579, 793 genes, copy number 11–30 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 793. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
